Somatic mutation profile of tumor specimen TCGA-H5-A2HR-01A (aliquot TCGA-H5-A2HR-01A-11D-A17W-09) from TCGA case TCGA-H5-A2HR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.1 years (25,986 days).
Specimen TCGA-H5-A2HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b8d470-99ec-4a2a-848f-7d41a0b3d0c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H5-A2HR-10A (Blood Derived Normal), aliquot TCGA-H5-A2HR-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e0457d-8a20-4359-be85-6c69fd6fb598

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 30/33 reads (91%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ANXA3 | c.628A>C p.K210Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV99363868; called by muse, mutect2, varscan2
- CDK19 | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.593); catalogued as rs773263211, COSV100098952; called by muse, mutect2, varscan2
- CYP1A1 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); catalogued as COSV101122365, COSV101122375; called by muse, mutect2, varscan2
- DNAJC22 | c.291T>G p.I97M | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV101222590; called by muse, mutect2, varscan2
- DPM1 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100857722, COSV100857742; called by muse, mutect2
- ENO1 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.594); catalogued as rs750183904, COSV99318935; called by muse, mutect2, varscan2
- GNA14 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs756624939, COSV59020348; called by muse, mutect2, varscan2
- HSPG2 | c.12895C>A p.L4299M | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100760879; called by muse, mutect2, varscan2
- KLC2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs767727284, COSV57581963, COSV57584709; called by muse, mutect2, varscan2
- MBOAT7 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201012145; called by muse, mutect2, varscan2
- MIF4GD | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | catalogued as rs764002197, COSV55453787, COSV99821632; called by muse, mutect2, varscan2
- NEDD4 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV100163992; called by muse, mutect2, varscan2
- NEURL1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs201830019, COSV100872627; called by muse, mutect2, varscan2
- NOL4 | c.712del p.S239Afs*66 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as COSV52338819, COSV99305001; called by mutect2, pindel, varscan2
- OR2J3 | c.922A>T p.M308L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101013652; called by muse, mutect2, varscan2
- PLXNB2 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100834082, COSV100834224, COSV63783405; called by muse, mutect2
- PRRG4 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99141420; called by muse, mutect2
- PTPRM | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs753717359, COSV59873277; called by muse, mutect2
- PTPRN2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs558350837, COSV101235100; called by muse, mutect2
- PTPRT | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100629374; called by muse, mutect2, varscan2
- RANBP2 | c.3559G>A p.G1187S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312863; called by muse, mutect2, varscan2
- RBBP5 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52706451; called by muse, mutect2
- SIGLEC1 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs200143991; called by muse, mutect2, varscan2
- SPIN3 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.371); catalogued as COSV100888490; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs763130641; called by mutect2, varscan2
- STK36 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs564387523, COSV99831759; called by muse, mutect2, varscan2
- SUFU | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1283661186, COSV100883147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D17 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs756847586, COSV99680856; called by muse, mutect2, varscan2
- TMEM106B | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101188862, COSV67543714; called by muse, mutect2, varscan2
- UGT2B17 | c.704A>C p.Q235P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV100497282; called by muse, mutect2, varscan2
- ZC3H6 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100674785; called by muse, mutect2, varscan2
- RAC2 | c.323C>A p.T108K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2
- USP25 | c.3115_3116del p.R1039Ifs*14 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.3126T>C p.D1042= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100372249; called by muse, mutect2, varscan2
- CFAP46 | c.7233C>T p.D2411= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV99583979, COSV99585329; called by muse, mutect2, varscan2
- COX11 | c.192G>A p.R64= | Silent (SNP) | VAF 144/154 reads (94%) | catalogued as rs762553883, COSV100174076; called by muse, mutect2, varscan2
- F5 | c.4518A>G p.E1506= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100889196; called by muse, mutect2
- PSORS1C1 | c.286C>T p.L96= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99456234; called by muse, mutect2, varscan2
- SMC2 | c.3309C>T p.L1103= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99659458; called by muse, mutect2, varscan2
- SUSD2 | c.114G>A p.L38= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as rs1460152381, COSV99573776; called by muse, mutect2, varscan2
- ZC3H7A | c.972G>A p.S324= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs942082404, COSV100865571; called by muse, mutect2, varscan2
- ZNF784 | c.876G>A p.S292= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1186711486, COSV100323257; called by muse, mutect2, varscan2
- PRSS3 | c.-97C>G | 5'UTR (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100725667; called by muse, mutect2, varscan2
